Somatic mutation profile of tumor specimen TCGA-A2-A0T4-01A (aliquot TCGA-A2-A0T4-01A-31D-A099-09) from TCGA case TCGA-A2-A0T4, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.6 years (22,849 days).
Specimen TCGA-A2-A0T4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9844ac70-7b2e-4e8f-82c1-6d2cff8ddab7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0T4-10A (Blood Derived Normal), aliquot TCGA-A2-A0T4-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65e279fb-5613-485a-90f6-3c530f3142ea

The open-access MAF lists 35 somatic variants for this specimen: 27 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 20, Silent 8, Splice Site 2, In Frame Del 2, Nonsense Mutation 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 8/53 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AMPD3 | c.551C>T p.P184L (on ENST00000396553 / NM_001025389.2; = p.P193L on NM_000480.3) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs774075201, COSV101158216; called by muse, mutect2
- CNNM1 | c.2711C>G p.T904R | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.057); catalogued as COSV63202967; called by muse, mutect2, varscan2
- CPT1A | c.1450C>G p.L484V | Missense Mutation (SNP) | VAF 82/239 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.262); catalogued as COSV55759326; called by muse, mutect2, varscan2
- FAM193A | c.3704G>C p.R1235T (on ENST00000324666 / NM_001256666.1; = p.R1194T on NM_003704.3) | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61197045; called by muse, mutect2, varscan2
- GPR37 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); catalogued as rs538782485, COSV58258825; called by muse, mutect2, varscan2
- HMGCLL1 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as COSV51449324; called by muse, mutect2, varscan2
- HMGCLL1 | c.13C>G p.P5A | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV51449334; called by muse, mutect2, varscan2
- IL1R2 | c.88T>A p.F30I | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV60208711; called by muse, mutect2, varscan2
- KDM6A | c.654+2T>G p.X218_splice | Splice Site (SNP) | VAF 37/143 reads (26%) | catalogued as COSV65043712; called by muse, mutect2, varscan2
- LRP2 | c.7850G>T p.R2617L | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55543674, COSV55566491; called by muse, mutect2, varscan2
- MEN1 | c.839+2T>G p.X280_splice | Splice Site (SNP) | VAF 30/94 reads (32%) | catalogued as COSV53640623; called by muse, mutect2, varscan2
- MFSD11 | c.149C>G p.T50S | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.811); catalogued as COSV60627014; called by muse, mutect2, varscan2
- MRGPRX4 | c.56A>T p.E19V | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100049797; called by muse, mutect2
- NLRC4 | c.2771T>C p.I924T | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV61592968, COSV61594075; called by muse, mutect2, varscan2
- PBDC1 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as COSV64896068; called by muse, mutect2, varscan2
- SF3B2 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1040369668, COSV59429554; called by muse, mutect2, varscan2
- SPEG | c.3887G>T p.G1296V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56676412; called by muse, mutect2, varscan2
- THSD7A | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs757185210, COSV70269721; called by muse, mutect2, varscan2
- TIGAR | c.60A>T p.K20N | Missense Mutation (SNP) | VAF 8/245 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV99463867; called by muse, mutect2
- ZIC4 | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.511); catalogued as COSV67173343; called by muse, mutect2, varscan2
- ZMIZ2 | c.1786G>A p.V596M | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as COSV54810072; called by muse, mutect2, varscan2
- ZNF618 | c.1156C>T p.Q386* (on ENST00000374126 / NM_001318042.2; = p.Q293* on NM_133374.2) | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | catalogued as COSV55926776; called by muse, mutect2, varscan2
- CDH1 | c.2268dup p.E757* | Frame Shift Ins (INS) | VAF 23/86 reads (27%) | called by mutect2, pindel, varscan2
- CTPS2 | c.432del p.I145Lfs*60 | Frame Shift Del (DEL) | VAF 19/111 reads (17%) | called by mutect2, pindel, varscan2
- HCFC1R1 | c.184_186del p.E62del | In Frame Del (DEL) | VAF 10/100 reads (10%) | called by pindel, varscan2
- ZFP36L1 | c.526_528del p.I176del | In Frame Del (DEL) | VAF 10/33 reads (30%) | called by mutect2, pindel, varscan2
- ARL4A | c.543A>G p.K181= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs1172200396, COSV63319581; called by muse, mutect2
- FUBP1 | c.1848T>C p.A616= | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as COSV53936001; called by muse, mutect2, varscan2
- HMGCLL1 | c.150C>G p.V50= | Silent (SNP) | VAF 58/121 reads (48%) | catalogued as COSV51449314, COSV99232029; called by muse, varscan2
- IL11RA | c.78C>T p.C26= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1439230184, COSV58841101; called by muse, mutect2, varscan2
- PCDHGA12 | c.1752C>A p.P584= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV52753566, COSV52762013; called by muse, mutect2, varscan2
- PPCDC | c.540C>T p.A180= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV61625529; called by muse, mutect2, varscan2
- SLC25A48 | c.141C>T p.R47= | Silent (SNP) | VAF 32/124 reads (26%) | catalogued as rs376435728; called by muse, mutect2, varscan2
- TDRKH | c.1200G>A p.K400= | Silent (SNP) | VAF 18/125 reads (14%) | catalogued as COSV58619010; called by muse, mutect2, varscan2
